Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8002, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8002-01A (Primary Tumor).

[page 1 of 6]
Patient Results

TCGA-HZ-8002

Surgical Pathology (Copath)

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

- (A) Falciform ligament, resection:
- 1) Benign fibroadipose tissue.
- 2) Negative for malignancy.
- (B) Lymph node, lesser omentum, biopsy: One lymph node, negative for metastasis (0/1).
- (C) Lymph node, posterior portal, biopsy: Two lymph nodes, negative for metastasis (0/2).
- (D) Bile duct margin, biopsy: Negative for malignancy.
- (E) Pancreatic margin, biopsy: Negative for malignancy.
- (F) Stomach, pancreaticoduodenectomy, partial gastrectomy and cholecystectomy (Whipple resection):
- 1) Invasive ductal adenocarcinoma, moderately differentiated (see Synoptic Report).
- 2) The tumor is 3.1 cm in greatest dimension.
- 3) All surgical margins are free of involvement by tumor.
- 4) Four of thirty-three total lymph nodes are positive for metastatic adenocarcinoma (4/33).
- 5) Pathologic stage: pT3N1.
- 6) Chronic pancreatitis
- 7) Gallbladder with chronic cholecystitis with cholelithiasis.
- 8) Stomach and duodenum with no mucosal histopathologic abnormality.
- (G) Lymph node, superior pancreatic, excision: Four lymph nodes, negative for metastasis (0/4).
- (H) Lymph node, celiac, biopsy: One lymph node, negative for metastasis (0/1).
- Synoptic Report:
- Specimen:
- Head of pancreas.
- Duodenum.
- Stomach.
- Common bile duct.
- Gallbladder.
- Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy, partial gastrectomy, cholecystectomy.
- Tumor Site: Pancreatic head.
- Tumor Size:
- Greatest Dimension: 3.1 cm.
- Additional Dimensions: 2.5 x 2.4 cm
- Histologic Type: Ductal adenocarcinoma.
- Histologic Grade: G2; Moderately differentiated.
- Microscopic Tumor Extension:

[page 2 of 6]
Patient Results

Tumor invades ampulla of Vater.
Tumor invades duodenal wall.
Tumor extends into peripancreatic soft tissues.
Margins:
Margins uninvolved by invasive carcinoma.
Distance of invasive carcinoma from closest margin: 5 mm
(posterior pancreatic soft tissue margin)
Margins uninvolved by carcinoma in situ.
Lymphovascular Invasion: Present.
Perineural Invasion: Present, extensive.
Pathologic Staging:
Primary Tumor: pT3: Tumor extends beyond the pancreas but
without involvement of the celiac axis or the superior
mesenteric artery.
Regional Lymph Nodes: pN1: Regional lymph node
metastasis.
Number of Lymph Nodes Examined: 33 (including
specimens B,C,F,G and H).
Number of Lymph Nodes Involved: 4
Distant Metastasis: MX: Not applicable.
Additional Pathologic Findings:
Pancreatic intraepithelial neoplasia (highest grade: PanIN
3).
Chronic pancreatitis.
Chronic cholecystitis with cholelithiasis.

Comments:

This case has been reviewed and the diagnosis approved by
consulting departmental surgical pathology staff.

'The gross description and all microscopic slides have been
reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Falsiform ligament
B: Lesser omentum lymph node
C: posterior portal lymph node
D: Bile duct margin
E: Pancreatic margin
F: Stomach, jejunum, gallbladder, duodenum, head of pancreas
G: Superior pancreatic lymph node
H: Celiac lymph node

Clinical History:

{Not Provided}

Intraoperative Consultation:

Time Received:

[page 3 of 6]
Patient Results

Time Reported: [REDACTED]

FSD1: Bile duct margin: Negative for malignancy (1 block).

FSE1: Pancreatic margin: Negative for malignancy (1 block)

Gross Description:

(A) (falciform ligament) Received in formalin is a lobulated fragment of fibrofatty tissue measuring 7.5 x 3.5 x 1.0 cm, consistent with falciform ligament. Serially sectioning the specimen reveals a firm fibrous ligamentous structure measuring up to 5 mm in diameter, running nearly the entire longitudinal axis of the specimen. Surrounding the ligament is lobulated adipose tissue. No nodules or masses are identified. A representative section of the ligament with surrounding fibroadipose tissue is submitted in cassette A1.

(B) (lesser omentum lymph nodes) Received in formalin is an irregular fragment of fibrofatty tissue measuring 3.0 x 1.5 x 1.0 cm. Within the fragment is identified a single tan, rubbery lymph nodes measuring up to 1.3 cm in greatest dimension. The lymph node is bisected and submitted in cassette B1. The remaining tissue fragments are submitted entirely in cassette B2.

(C) (posterior portal lymph node) Received in formalin are two firm, tan tissue fragments, measuring up to 6 mm and 4 mm in greatest dimension, respectively. The fragments are submitted entirely in cassette C1.

(D) (bile duct margin - FS) Received fresh for intraoperative consultation is a segment of dilated bile duct measuring 1.0 cm in diameter and 2 mm in length. The specimen is submitted entirely for frozen section evaluation in cassette FSD1.

(E) (pancreatic margin - FS) Received fresh for intraoperative consultation is an irregular, flat section of pancreas measuring 1.8 x 1.2 x 0.5 cm. A single stitch is present at the true margin. Following removal of the stitch, the specimen is submitted entirely for frozen section evaluation in cassette FSE1.

(F) (stomach, jejunum, gallbladder, duodenum, and head of pancreas)

Specimen components and dimensions: Received in formalin is a Whipple resection specimen including a portion of distal stomach, proximal duodenum, pancreatic head, and attached gallbladder. The distal stomach measures 6.5 cm in length with a diameter ranging from 4.5 to 7.0 cm. The proximal gastric resection margin is stapled shut. The segment of duodenum measures 15.0 cm in length with an average diameter of 2.5 cm. The pancreatic head measures 5.0 cm from left to right, 4.7 cm from superior to inferior, and 4.5 cm from anterior to

[page 4 of 6]
Patient Results

posterior. The attached gallbladder measures 11.0 x 4.0 x 2.0 cm and is attached to the main specimen by a cystic duct measuring 1.5 cm in length and the common bile duct measuring 5.5 cm in length with an average diameter of 0.7 cm. The distal duodenal resection margin is stapled shut. Although the pancreatic resection was submitted previously for frozen section evaluation, the new resection margin is inked red. Additional areas of the pancreas are inked as follows: Green - uncinate margin; yellow - anterior; black - deep; and purple - vascular margin. A stent is present in the distal common bile duct. Size, appearance, and location of tumor: Within the pancreatic head in the area of the ampulla is an irregular, firm, white mass with irregular borders, measuring 3.1 x 2.5 x 2.4 cm. On cut surface, the mass is firm and white tan with peripheral spiculation and focal areas of possible central hemorrhage. Gross impression of invasive growth: The mass displays an indistinct border but clearly invades into the duodenal wall and possibly into the duodenal mucosa. The mass also appears to extensively invade the peripancreatic soft tissue. The mass surrounds the ampulla and common bile duct.

Closest resection margins and distance: Although the tumor borders are indistinct, the mass grossly measures 1.8 cm from the pancreatic resection margin, 8 mm from the uncinate margin, 8 mm from the vascular margin, 5 mm from the nearest posterior pancreatic soft tissue resection margin, 3.8 cm from the bile duct resection margin, 7.0 cm from the distal duodenal resection margin, and 8.5 cm from the proximal gastric resection margin at its nearest point.

Other findings: Within the gallbladder are innumerable, irregular, yellow, polyhedral stones, measuring up to 8 mm in greatest dimension.

Uninvolved tissues: The stomach wall measures 8 mm in average thickness. The gastric mucosa is soft, tan, and velvety without nodules, ulceration, or hemorrhage. The uninvolved duodenal wall measures 7 mm in average thickness. The duodenal mucosa is soft, tan, and velvety with normal mucosal folds, without additional nodules, ulceration, or hemorrhage. The gallbladder wall measures 6 mm in average thickness. The gallbladder mucosa is rough and tannish brown without ulceration or hemorrhage. No cholesterosis is identified.

Lymph nodes attached: Within the peripancreatic soft tissues and surrounding the common bile duct are 26 lymph nodes ranging in size from 5 mm to 2.1 cm in greatest dimension.

Blocks submitted:

- F1 - representative gastric resection margin
- F2 - distal duodenal resection margin
- F3 - representative gallbladder
- F4 - representative stomach

[page 5 of 6]
Patient Results

F5 - representative uninvolved duodenum
F6 - mass to ampulla and common bile duct
F7 - mass to nearest uncinate and vascular margins
F8 - representative uninvolved pancreas
F9 - mass to duodenum
F10 - mass to peripancreatic soft tissue
F11 - representative common bile duct
F12-F13 - additional representative sections of mass to peripancreatic soft tissue
F14 - one lymph node, bisected
F15 - one lymph node, bisected
F16 - one lymph node
F17-F18 - largest lymph node, bisected
F19 - one lymph node, bisected
F20 - one lymph node, bisected
F21 - five lymph nodes
F22 - four lymph nodes
F23 - four lymph nodes
F24 - four lymph nodes
F25 - three lymph nodes

(G) (superior pancreatic lymph node) Received in formalin is an irregular fragment of dark tan, rubbery tissue measuring up to 1.4 cm in greatest dimension. Within this fragment are identified two possible lymph nodes, measuring up to 6 mm and 8 mm in greatest dimension. The larger possible lymph node is submitted in cassette G1. The smaller lymph node and remaining tissue fragments are submitted entirely in cassette G2.

(H) (celiac lymph node) Received in formalin is an irregular, lobulated fragment of fibroadipose tissue measuring 1.5 x 1.5 x 0.8 cm. Within this fragment is identified a single, tan, rubbery lymph node measuring up to 0.9 cm in greatest dimension. The specimen is bisected and submitted entirely in cassettes H1-H2.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at the [REDACTED]. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used

[page 6 of 6]
Patient Results

to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file e9de0d2f-868b-48ab-9e4f-f880f9d30ad2 (TCGA-HZ-8002.E0B6576A-CA98-4A40-A8E8-AA1E282E570F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).